CPTAC case C3N-04294 — Skin — Nevi and Melanomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Nevi and Melanomas; Primary site: Skin. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/5959a640-1b1d-4016-ae24-715f98c9f28b

Demographics
Sex at birth: male; Race: white; Year of birth: 1954; Vital status: Dead; Days to death: 211 days; Year of death: 2018; Cause of death: Cancer Related; Country of birth: Poland.

Diagnoses (1)
1. Malignant melanoma, NOS: ICD-O-3 morphology code: 8720/3; Tissue or organ of origin: Skin, NOS; Site of resection or biopsy: Skin, NOS; Age at diagnosis: 64.0 years (23,388 days); Year of diagnosis: 2018; AJCC staging edition: 8th; AJCC clinical M: M0; AJCC pathologic N: N3b; AJCC pathologic M: M0; AJCC pathologic stage: Stage IIID; Residual disease: R0; Last known disease status: With tumor; Days to last known disease status: 211 days; Progression or recurrence: no; Days to last follow up: 167 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 5 cm; Lymph node involvement: Positive; Lymph nodes positive: 20; Lymph nodes tested: 35; Margin status: Indeterminate.
   Radiation Therapy, NOS — whether it was given is not recorded by GDC; Treatment outcome: Persistent Disease.

Follow-up (1 entry)
- Days to follow up: 167 days; Disease response: With Tumor; Karnofsky performance status: 0; ECOG performance status: 5.

Exposures
- Tobacco smoking status: Lifelong Non-Smoker; Alcohol history: Yes; Alcohol intensity: Not Heavy Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3N-04294-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Biospecimen anatomic site: Lymph Node; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -3 days; Initial weight: 164 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3N-04294-21: Section location: Lymph node; Percent tumor nuclei: 80; Percent necrosis: 0.
- Sample C3N-04294-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -3 days; Method of sample procurement: Blood Draw.
